Surgical pathology report (de-identified scan), TCGA case TCGA-3X-AAVC, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Alberta Health Services, specimen TCGA-3X-AAVC-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Time Received

Time Transmitted

Ordering Provider

Relevant Information

Location

Copied To

Report Patient

Name:

Demographics (for
verification purposes)

Date of Birth:

Sex: F

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number

Collected Date/Time

Received Date/Time

Pathologist

Specimen Description

- A. Liver segment 4-5 and gallbladder
- B. Portal tissue

Clinical Information

Gallbladder cancer.

Infectious patient: No

Immunocompromised: No

History of neoplasm: No

Diagnosis

A. Liver (segment 4-5) and Gallbladder, Resection:

- Poorly differentiated adenocarcinoma (choleangiocarcinoma) arising within mid and distal portion of the gallbladder, 3.8 cm in greatest dimension (see Synoptic Report)
- Chronic cholecystitis and cholelithiasis with perforation (no tumor at the perforation site)
- Resection margin (liver and peritoneal surfaces) free of tumor

B. Portal Tissue, Resection:

- Fibroadipose tissue with non-specific inflammation
- No neoplasia

Reported by:

Electronically signed by:

Verified:

Responsible Resident:

ICD-O-3

Cholangiocarcinoma 8160/3
Site: ^{CUS} Bile duct NOS C24.0
~~HB~~ Gallbladder C23.9

Op 5/21/14

[page 2 of 3]
Synoptic Report
A: Gallbladder, Microscopic
HISTOLOGIC TYPE:
Adenocarcinoma
HISTOLOGIC GRADE:
G3: Poorly differentiated
MICROSCOPIC TUMOR EXTENSION:
Tumor invades muscle layer

MARGINS:

Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 1.3 mm
Specified margin: Liver parenchymal margin

LYMPH-VASCULAR INVASION:

Not identified

PERINEURAL INVASION:

Not identified

PRIMARY TUMOR (pT):

pT1b: Tumor invades muscle layer

REGIONAL LYMPH NODES (pN):

Number examined: 1

Number involved: 0

ADDITIONAL PATHOLOGIC FINDINGS:

Cholelithiasis

Chronic cholecystitis

Acute cholecystitis

Gross Description

Received are specimen containers A to B. All requisitions and specimen containers are labelled with the patient's name, The cassettes and identifiers are labelled with the Surgical Number

A. Specimen is received fresh. The container is designated "A. Liver segment 4-5 and gallbladder". The specimen consists of a gallbladder with attached liver tissue. The gallbladder measures 11.0 cm in length and 4.0 cm in diameter. There is a cholelithiasis measuring 1.5 cm in greatest diameter perforating through the gallbladder at the cystic duct end. This perforation site has been painted yellow. There is also an indurated area on the anterior side of the gallbladder without evidence of perforation externally and this area has been painted orange. The indurated area at the anterior surface of the gallbladder appears to be fibrosed with some necrosis on sectioning without grossly evident tumor. The external surface of the liver resection margin has been painted blue and appears to be uninvolved by mass lesions. The attached adjacent adipose tissue measures 9.7 x 6.0 x 1.7 cm in greatest dimension. Within the gallbladder is a tan/white, friable, polypoid lesion measuring 3.8 x 2.4 x 2.5 cm in greatest dimension roughly arising from the wall and occupying the whole lumen of the mid portion of the gallbladder. Adjacent to this and close to a cystic duct is the perforated cholelithiasis that is dark brown and ovoid in shape measuring 3.9 x 2.2 x 2.2 cm in dimension. The tumor is seen to be attached to the perihepatic wall of the gallbladder and has a maximum depth of invasion 1.1cm through the gallbladder wall into the hepatic parenchyma as measured from the gallbladder mucosa to the deepest portion within the adjacent liver parenchyma. At this area, the maximum depth of invasion in the hepatic parenchyma itself as measured from the outer surface of the perihepatic gallbladder wall into the liver parenchyma is 0.3 cm. There is necrosis and hemorrhage in the central part of the tumor. Sections are submitted as follows:

- A1 - shaved cystic duct margin.
- A2 - grossly uninvolved part of the liver and gallbladder.
- A3 - site of the cholelithiasis perforation at the end towards the cystic duct.
- A4 - maximum depth of tumor invasion, split in half
- A5 - maximum depth of tumor invasion
- A6 - area of gallbladder wall induration.

[page 3 of 3]
B. Specimen is received fresh and fixed overnight in formalin. The container is designated "B. portal tissue". Within it is a tan/brown fibrous tissue with hemorrhage. The tissue measures 1.2 x 0.4 x 0.2 cm in maximum dimension. The specimen is bisected and submitted in toto in one cassette, B1.

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 45d8530b-0169-462f-b91e-f2d4a8a5738b (TCGA-3X-AAVC.88206A8B-257B-4C0F-B42C-905DEA9483FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).